Gene-level copy-number profile of tumor specimen C3L-00359-01 from CPTAC case C3L-00359, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 73.5 years (26,864 days).
Specimen C3L-00359-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee5e869c-e15f-4899-9e12-377920609b42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00359-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/02ce333e-3c67-447a-81a0-1b19770235e4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,345; copy number 3: 2; copy number 4: 53,364; copy number 5: 118; copy number 6: 2,543; copy number 7: 10; copy number 8: 1; copy number 9: 3; copy number 10: 1; copy number 11: 1; copy number 12: 1; copy number 13: 4; copy number 14: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–73,865, 5 genes, copy number 14 (within-gene range 4–14): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:39,983,793–40,106,611, 1 gene, copy number 9 (within-gene range 7–9): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes, copy number 9: AL773545.3, CDRT15P14.
- chr9:61,190,003–61,212,373, 4 genes, copy number 13: SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr9:61,944,232–61,945,136, 1 gene, copy number 12: CR769775.1.
- chr9:64,810,865–64,836,341, 2 genes, copy number 10–11: BNIP3P4, AL359955.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
